Somatic mutation profile of tumor specimen TCGA-EM-A3AR-01A (aliquot TCGA-EM-A3AR-01A-12D-A20C-08) from TCGA case TCGA-EM-A3AR, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 41.9 years (15,313 days).
Specimen TCGA-EM-A3AR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86c03298-4400-4036-8546-6a6bc170555e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A3AR-10A (Blood Derived Normal), aliquot TCGA-EM-A3AR-10A-01D-A20C-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92b74b54-e378-4f28-abcc-eaf47259e128

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- KCNIP3 | c.484A>G p.T162A | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as COSV54668111; called by muse, mutect2
- ZMIZ2 | c.789G>C p.Q263H | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs780858787, COSV54807663; called by muse, mutect2, varscan2
- ABCG8 | c.1017G>A p.R339= | Silent (SNP) | VAF 12/124 reads (10%) | catalogued as rs375807484; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL27A1 | c.318C>T p.S106= | Silent (SNP) | VAF 26/178 reads (15%) | catalogued as rs753526489, COSV61925527; called by muse, mutect2, varscan2
